Somatic mutation profile of tumor specimen 0DTHM8 from CCDI case PBCJWJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.7 years (6,832 days).
Specimen 0DTHM8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b36a7f9-f2a5-4879-bcbc-7ed148c05809.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTHME (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96542736-1f43-4605-a86a-efa0b918e4c6

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR5D14 | c.278G>T p.S93I | Missense Mutation (SNP) | VAF 55/516 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV59457580; called by muse, mutect2, varscan2
- SETD2 | c.6325C>T p.R2109* | Nonsense Mutation (SNP) | VAF 22/522 reads (4%) | catalogued as COSV57430221; called by muse, mutect2
- HYDIN | c.14923G>A p.A4975T | Missense Mutation (SNP) | VAF 61/676 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2
- MTMR7 | c.1501A>C p.S501R | Missense Mutation (SNP) | VAF 17/609 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PIEZO2 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 46/443 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT4 | c.11367A>G p.K3789= | Silent (SNP) | VAF 42/658 reads (6%) | called by muse, mutect2
- GABRE | c.867C>T p.S289= | Silent (SNP) | VAF 150/727 reads (21%) | catalogued as rs151160537, COSV64819236; called by muse, mutect2, varscan2
- BRAT1 | c.1771-188T>G | Intron (SNP) | VAF 22/228 reads (10%) | called by muse, mutect2, varscan2
